Somatic mutation profile of tumor specimen TCGA-KK-A7B2-01A (aliquot TCGA-KK-A7B2-01A-12D-A32B-08) from TCGA case TCGA-KK-A7B2, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.0 years (24,845 days).
Specimen TCGA-KK-A7B2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11e92fae-e1ae-4f5e-b701-1d7b1fe12b21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7B2-11A (Solid Tissue Normal), aliquot TCGA-KK-A7B2-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41a7840-21ec-4092-b556-fe9ce6b91d06

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT12 | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100296872; called by muse, mutect2
- ACTN3 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101557830; called by muse, mutect2
- ASPHD1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs770181762, COSV100435339; called by muse, mutect2, varscan2
- ATF7IP2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs763026987, COSV100202586; called by muse, mutect2
- FOSB | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs143780767; called by muse, mutect2
- IFTAP | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100531062; called by muse, mutect2
- KIAA2026 | c.1795A>T p.T599S | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV101198971; called by muse, mutect2
- OR2B11 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141064927, COSV100275824; called by muse, mutect2
- OR8H1 | c.194A>C p.H65P | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100477028, COSV57294119; called by muse, mutect2
- PGS1 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV99428199; called by muse, mutect2
- PPL | c.4751C>T p.S1584L | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs768926495, COSV99277855; called by muse, mutect2
- SLC35C1 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV100029374; called by muse, mutect2
- ZMYM3 | c.2736del p.I912Mfs*2 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.2724C>T p.P908= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99170536; called by muse, mutect2
- LAT | c.120C>G p.S40= | Silent (SNP) | VAF 12/266 reads (5%) | catalogued as COSV100209042; called by muse, mutect2
- PCDHA8 | c.1611G>A p.A537= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV65327188; called by muse, mutect2
- VWA3B | c.489A>G p.L163= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV101346010; called by muse, mutect2
